Somatic mutation profile of tumor specimen MMRF_2102_1_BM_CD138pos (aliquot MMRF_2102_1_BM_CD138pos_T1_KHS5U_L08799) from MMRF case MMRF_2102, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.3 years (27,884 days).
Specimen MMRF_2102_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7da898a8-0027-4cca-90cb-288a991287b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2102_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2102_1_PB_WBC_C3_KHS5U_L08804; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/252a8727-03b5-4827-8c67-e02250b4b2e3

The open-access MAF lists 86 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 28, Missense Mutation 26, Silent 12, Intron 7, 5'UTR 4, 3'Flank 3, Frame Shift Del 3, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 55/131 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CALCR | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.205); catalogued as COSV100810845; called by muse, mutect2, varscan2
- CALN1 | c.148C>T p.R50W (on ENST00000329008 / NM_001017440.3; = p.R92W on NM_031468.4) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61146464, COSV61158154; called by muse, mutect2, varscan2
- FAM43A | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61673391; called by muse, mutect2, varscan2
- PIEZO2 | c.1030A>G p.M344V | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1442335119; called by muse, mutect2, varscan2
- PURB | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1432294300; called by muse, mutect2, varscan2
- SFSWAP | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.289); catalogued as rs762743632; called by muse, mutect2, varscan2
- SGCZ | c.405A>T p.L135F | Missense Mutation (SNP) | VAF 151/378 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99062842; called by muse, mutect2, varscan2
- SGMS2 | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 93/222 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV62989408; called by muse, mutect2, varscan2
- SLC12A7 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746702666; called by muse, mutect2, varscan2
- ST8SIA1 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as rs745747495, COSV53951274; called by muse, mutect2, varscan2
- SULT1E1 | c.793A>T p.N265Y | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56947731; called by muse, mutect2, varscan2
- TDRD15 | c.5047del p.L1683Cfs*7 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | catalogued as COSV68266444; called by mutect2, pindel, varscan2
- ADAMTS9 | c.2677C>T p.P893S | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- AKAP11 | c.1796T>C p.L599P | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- B3GNT2 | c.649T>G p.F217V | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- CENPE | c.1067A>G p.K356R | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- COL28A1 | c.2576A>T p.D859V | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- CYP46A1 | c.1031del p.F344Sfs*18 | Frame Shift Del (DEL) | VAF 67/166 reads (40%) | called by mutect2, pindel, varscan2
- DEDD2 | c.773_785del p.Y258Sfs*6 | Frame Shift Del (DEL) | VAF 73/191 reads (38%) | called by mutect2, pindel, varscan2
- DSC1 | c.1831C>G p.L611V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GOLGB1 | c.3439A>C p.I1147L | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GOT1 | c.1075G>C p.G359R | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKJ5 | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 102/220 reads (46%) | called by muse, varscan2
- LYZL1 | c.568G>T p.G190C (on ENST00000375500; = p.G144C on NM_032517.6) | Missense Mutation (SNP) | VAF 197/435 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPAT | c.4106dup p.R1370Afs*4 | Frame Shift Ins (INS) | VAF 21/64 reads (33%) | called by mutect2, pindel, varscan2
- REXO5 | c.1542A>C p.K514N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- RYR2 | c.13481A>C p.Y4494S | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SETD2 | c.4597T>A p.C1533S | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- SRRM2 | c.7198C>G p.P2400A | Missense Mutation (SNP) | VAF 95/229 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- TENT5C | c.858dup p.K287Efs*12 | Frame Shift Ins (INS) | VAF 21/164 reads (13%) | called by mutect2, pindel, varscan2
- ADPRHL1 | c.195C>T p.T65= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as rs369993693; called by muse, mutect2, varscan2
- COPB2 | c.240G>A p.Q80= | Silent (SNP) | VAF 83/192 reads (43%) | catalogued as COSV60812653; called by muse, mutect2, varscan2
- DAG1 | c.351G>A p.L117= | Silent (SNP) | VAF 50/116 reads (43%) | called by muse, mutect2, varscan2
- HOMER3 | c.27C>T p.I9= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV55355358; called by muse, mutect2, varscan2
- MAML2 | c.1974G>A p.Q658= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs571656416, COSV73262854, COSV73262892; called by muse, mutect2, varscan2
- MST1R | c.393G>A p.A131= | Silent (SNP) | VAF 29/251 reads (12%) | catalogued as rs780104920; called by muse, varscan2
- OR8J1 | c.345G>T p.L115= | Silent (SNP) | VAF 54/126 reads (43%) | catalogued as COSV57319303; called by muse, mutect2
- SERTAD4 | c.405G>A p.L135= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as COSV100882678, COSV65399082; called by muse, mutect2, varscan2
- SLC24A3 | c.1545C>T p.T515= | Silent (SNP) | VAF 71/185 reads (38%) | called by muse, mutect2, varscan2
- TNRC18 | c.2217C>T p.L739= | Silent (SNP) | VAF 25/164 reads (15%) | catalogued as rs373724208; called by muse, mutect2, varscan2
- UGT1A4 | c.6C>T p.A2= | Silent (SNP) | VAF 81/165 reads (49%) | called by muse, mutect2, varscan2
- ZNF467 | c.1485C>T p.R495= | Silent (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.*2805C>T | 3'UTR (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- C4orf50 | c.*82T>A | 3'UTR (SNP) | VAF 74/319 reads (23%) | called by muse, mutect2, varscan2
- CACNA1E | c.*402G>T | 3'UTR (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- CALN1 | c.*129G>T | 3'UTR (SNP) | VAF 51/118 reads (43%) | called by muse, mutect2, varscan2
- CCDC130 | c.400+45C>T | Intron (SNP) | VAF 92/189 reads (49%) | called by muse, mutect2, varscan2
- CFAP43 | c.*4C>T | 3'UTR (SNP) | VAF 26/56 reads (46%) | catalogued as rs370281201; called by muse, mutect2, varscan2
- CIRBP | c.502+152C>G | Intron (SNP) | VAF 79/243 reads (33%) | catalogued as rs773600819; called by muse, mutect2, varscan2
- CNGB3 | c.*620C>G | 3'UTR (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- COA5 | c.*744T>G | 3'UTR (SNP) | VAF 52/114 reads (46%) | called by muse, mutect2, varscan2
- CPNE8 | c.*530C>G | 3'UTR (SNP) | VAF 39/92 reads (42%) | called by muse, mutect2, varscan2
- CXXC4 | c.*2897A>G | 3'UTR (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- DUSP13 | c.*885C>T | 3'UTR (SNP) | VAF 12/35 reads (34%) | catalogued as rs141915692, COSV100403448, COSV100403828; called by muse, mutect2, varscan2
- ERP44 | c.*991C>A | 3'UTR (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- FAM170A | c.-153G>A | 5'UTR (SNP) | VAF 30/75 reads (40%) | catalogued as rs999663600; called by muse, varscan2
- FUOM | c.*70A>C | 3'UTR (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2
- HCN1 | c.*1385C>T | 3'UTR (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2, varscan2
- HMGCS1 | c.*1705A>G | 3'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- HOMEZ | c.*2683T>G | 3'UTR (SNP) | VAF 84/200 reads (42%) | called by muse, mutect2, varscan2
- IL1R1 | c.*86T>C | 3'UTR (SNP) | VAF 129/311 reads (41%) | called by muse, mutect2, varscan2
- INKA2 | c.*3390T>A | 3'UTR (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- MERTK | c.*144A>C | 3'UTR (SNP) | VAF 85/209 reads (41%) | called by muse, mutect2, varscan2
- MGAT4A | c.404-203del | Intron (DEL) | VAF 9/56 reads (16%) | catalogued as rs1443425006; called by mutect2, pindel, varscan2
- MRGPRF | c.*576G>A | 3'UTR (SNP) | VAF 48/124 reads (39%) | called by muse, mutect2, varscan2
- NDUFS2 | chr1:161214449 C>T | 3'Flank (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- NTRK1 | c.1502-52C>T | Intron (SNP) | VAF 13/41 reads (32%) | catalogued as rs1235956333; called by muse, mutect2, varscan2
- NTRK3 | chr15:87872990 T>A | 3'Flank (SNP) | VAF 38/93 reads (41%) | called by muse, mutect2, varscan2
- PHBP20 | n.408G>C | RNA (SNP) | VAF 38/80 reads (48%) | called by muse, mutect2, varscan2
- PRDM5 | c.*2375G>T | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- RAB24 | c.-391G>C | 5'UTR (SNP) | VAF 32/71 reads (45%) | catalogued as rs969671483; called by muse, mutect2, varscan2
- RNF144B | c.*2586del | 3'UTR (DEL) | VAF 8/50 reads (16%) | catalogued as rs200074356; called by pindel, varscan2
- RNF217 | c.*7984T>C | 3'UTR (SNP) | VAF 49/116 reads (42%) | called by muse, mutect2, varscan2
- SMAD2 | c.*5827_*5828del | 3'UTR (DEL) | VAF 37/125 reads (30%) | catalogued as rs1355493603; called by mutect2, pindel, varscan2
- SNX24 | c.*781T>C | 3'UTR (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- SSR1 | c.*3649T>C | 3'UTR (SNP) | VAF 66/158 reads (42%) | called by muse, mutect2, varscan2
- STK10 | c.-81C>T | 5'UTR (SNP) | VAF 19/43 reads (44%) | catalogued as rs1365097543; called by muse, mutect2, varscan2
- SYNE1 | c.23979-86T>C | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- TNFRSF11A | c.*458T>G | 3'UTR (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- TSEN34 | c.-4-17C>G | Intron (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- VAPB | c.-77G>A | 5'UTR (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- VDR | c.146+53G>A | Intron (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- XPC | c.*152A>G | 3'UTR (SNP) | VAF 57/149 reads (38%) | called by muse, mutect2, varscan2
- ZNF462 | c.*1288T>C | 3'UTR (SNP) | VAF 18/52 reads (35%) | called by muse, varscan2
- ZNF780A | chr19:40071465 A>C | 3'Flank (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
